Somatic mutation profile of tumor specimen 0DRPJ0 from CCDI case PBCGGM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 21.7 years (7,941 days).
Specimen 0DRPJ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9923ccd5-3a0c-41f9-b0d4-d749a05381bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRPJ7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6734f0-5bfe-4a07-89a5-b6b9ad1166a3

The open-access MAF lists 24 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Intron 3, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 143/683 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- DEK | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs774631500; called by muse, mutect2
- F13B | c.1535A>G p.Y512C | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 36/1202 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MARS1 | c.1770G>C p.E590D | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PRKAR2B | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 62/526 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC17 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 32/865 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZFYVE16 | c.782A>T p.K261M | Missense Mutation (SNP) | VAF 44/1178 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- ZNF214 | c.1192A>G p.S398G | Missense Mutation (SNP) | VAF 35/737 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.38); called by muse, mutect2
- ZXDB | c.1268T>A p.L423Q | Missense Mutation (SNP) | VAF 41/1124 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ATP12A | c.27C>T p.Y9= | Silent (SNP) | VAF 55/633 reads (9%) | catalogued as rs1449624098; called by muse, mutect2
- CEPT1 | c.588G>A p.A196= | Silent (SNP) | VAF 90/861 reads (10%) | catalogued as rs769589248, COSV64110866; called by muse, mutect2, varscan2
- KTN1 | c.387C>A p.V129= | Silent (SNP) | VAF 88/714 reads (12%) | called by muse, mutect2, varscan2
- NLRP4 | c.1218T>C p.G406= | Silent (SNP) | VAF 20/361 reads (6%) | called by muse, mutect2
- SAG | c.897G>C p.L299= | Silent (SNP) | VAF 69/652 reads (11%) | catalogued as rs780781792; called by muse, mutect2, varscan2
- SLC2A14 | c.120T>A p.V40= | Silent (SNP) | VAF 190/744 reads (26%) | called by muse, mutect2, varscan2
- STRADB | c.45A>G p.E15= | Silent (SNP) | VAF 28/988 reads (3%) | called by muse, mutect2
- TRIO | c.1563C>G p.S521= | Silent (SNP) | VAF 164/695 reads (24%) | called by muse, mutect2, varscan2
- ADAM22 | c.2576+64A>C | Intron (SNP) | VAF 57/471 reads (12%) | called by muse, mutect2, varscan2
- HNF4A | c.*18G>T | 3'UTR (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- IDH3G | c.*24T>G | 3'UTR (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- PSME1 | c.670-79T>C | Intron (SNP) | VAF 42/388 reads (11%) | called by muse, mutect2, varscan2
- SH2D1A | c.*48G>T | 3'UTR (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
